Somatic mutation profile of tumor specimen TCGA-CF-A47V-01A (aliquot TCGA-CF-A47V-01A-11D-A23U-08) from TCGA case TCGA-CF-A47V, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 52.7 years (19,265 days).
Specimen TCGA-CF-A47V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dce680bc-bf59-4ac2-a2a8-4d2ced45a5b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A47V-10A (Blood Derived Normal), aliquot TCGA-CF-A47V-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21222155-ca5f-46d9-9995-208f95dbcb0f

The open-access MAF lists 85 somatic variants for this specimen: 58 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 24, Nonsense Mutation 2, Splice Region 1, 3'UTR 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F11 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs281875250, CM121072, COSV53001710; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 146/174 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACVRL1 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV66360839; called by muse, mutect2, varscan2
- ADGRF1 | c.1342C>G p.Q448E | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV51947290; called by muse, mutect2, varscan2
- AFDN | c.3395A>T p.Y1132F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV60053962; called by muse, varscan2
- AGO1 | c.1447A>C p.I483L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV64596278; called by muse, mutect2, varscan2
- ALDH1B1 | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as COSV66620259; called by muse, mutect2, varscan2
- ANO4 | c.931C>T p.H311Y (on ENST00000392977 / NM_001286615.2; = p.H276Y on NM_178826.4) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV54609635; called by muse, mutect2, varscan2
- ASF1A | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57648524; called by muse, mutect2, varscan2
- ASGR1 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV52649489; called by muse, mutect2, varscan2
- ATR | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63390866; called by muse, mutect2, varscan2
- BBS10 | c.1375G>C p.D459H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV67913378; called by muse, mutect2, varscan2
- BEST3 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as rs757476199, COSV58304748; called by muse, mutect2, varscan2
- CCL22 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs867871956, COSV54659988, COSV54660213; called by muse, mutect2, varscan2
- CDHR2 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV56143943; called by muse, mutect2, varscan2
- CLEC11A | c.796C>G p.R266G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV51574922, COSV51574939; called by muse, mutect2, varscan2
- CYP27A1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as rs777527880, COSV99298395; called by muse, mutect2, varscan2
- DSCAML1 | c.2909G>A p.R970Q (on ENST00000321322; = p.R910Q on NM_020693.4) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.71); catalogued as rs754618507, COSV100355272; called by muse, varscan2
- ENTPD7 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65113096; called by muse, mutect2, varscan2
- FADD | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 157/199 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV57229736; called by muse, mutect2, varscan2
- GLI1 | c.1424C>G p.T475S | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV57366030; called by muse, mutect2, varscan2
- GRM5 | c.1577G>C p.G526A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as COSV59602069, COSV59624362; called by muse, mutect2, varscan2
- HTR1F | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV60390972; called by muse, mutect2, varscan2
- JMJD1C | c.5159C>T p.S1720F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59517429; called by muse, mutect2, varscan2
- LARP4B | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV60220093, COSV60221182, COSV60223373; called by muse, mutect2, varscan2
- MARK3 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV53508601; called by muse, varscan2
- MARK3 | c.1218G>C p.Q406H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.753); catalogued as COSV53514949; called by muse, mutect2, varscan2
- MCF2L2 | c.3090G>C p.E1030D | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV100193496, COSV61059928; called by muse, mutect2, varscan2
- MED19 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs913543176, COSV54708834; called by muse, mutect2, varscan2
- MED26 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs780507334, COSV54662525; called by muse, mutect2, varscan2
- MRGPRX3 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV66934711; called by muse, mutect2, varscan2
- MYH7 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100805853; called by muse, mutect2, varscan2
- NAA30 | c.206A>G p.H69R | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV53649556; called by muse, mutect2, varscan2
- NDE1 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV61269740, COSV61275725; called by muse, mutect2
- NRXN1 | c.4264A>G p.M1422V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60518022; called by muse, mutect2, varscan2
- OR10G7 | c.76T>C p.F26L | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.529); catalogued as rs1404289221, COSV57868541; called by muse, varscan2
- PLOD1 | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52149606; called by muse, mutect2, varscan2
- PLPPR5 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs777104367, COSV99587107; called by muse, mutect2, varscan2
- POGLUT3 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756678069, COSV60213919; called by muse, mutect2, varscan2
- PRPSAP2 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as COSV52067517; called by muse, mutect2, varscan2
- RAB13 | c.123C>T p.I41= | Splice Region (SNP) | VAF 31/42 reads (74%) | catalogued as COSV63933655, COSV63933723; called by muse, mutect2, varscan2
- RBBP8 | c.2251G>C p.E751Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV59095414; called by muse, mutect2, varscan2
- RYR3 | c.12019G>A p.D4007N (on ENST00000389232; = p.D4008N on NM_001036.6) | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756925363, COSV66803113; called by muse, mutect2, varscan2
- SACS | c.3784C>G p.H1262D | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV66543617, COSV66545735; called by muse, mutect2, varscan2
- SAMSN1 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53476403; called by muse, mutect2, varscan2
- SCML4 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs773253589, COSV64637581; called by muse, mutect2, varscan2
- SLC6A12 | c.1464G>A p.M488I | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV62885934; called by muse, mutect2, varscan2
- SLC6A12 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62885938; called by muse, mutect2, varscan2
- SMARCC2 | c.1576C>G p.P526A | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57223724; called by muse, mutect2, varscan2
- SPTAN1 | c.2596C>A p.H866N | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV63989365; called by muse, mutect2, varscan2
- TBC1D12 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV56557402; called by muse, mutect2, varscan2
- TMEM192 | c.47A>G p.Q16R | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV60585999; called by muse, mutect2, varscan2
- TNFRSF10D | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as COSV57037520; called by muse, mutect2, varscan2
- TSHR | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756016910, CM067067, CM067068, COSV53318855, COSV53329393; called by muse, mutect2, varscan2
- VWA8 | c.4649C>T p.S1550F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV64998610; called by muse, mutect2, varscan2
- ZKSCAN7 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56274249; called by muse, mutect2, varscan2
- ZNF700 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as COSV54314884; called by muse, mutect2, varscan2
- PRMT5 | c.1021A>T p.I341F | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- ACACA | c.6495C>T p.F2165= | Silent (SNP) | VAF 28/55 reads (51%) | called by muse, varscan2
- ACTB | c.846C>T p.I282= | Silent (SNP) | VAF 66/137 reads (48%) | catalogued as COSV59320797; called by muse, mutect2, varscan2
- ARAP3 | c.870C>T p.L290= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV53353887; called by muse, mutect2, varscan2
- ASNSD1 | c.1221C>T p.I407= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV53624702; called by muse, mutect2, varscan2
- CAPN13 | c.1731C>T p.F577= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99699982; called by muse, mutect2
- COL6A2 | c.2628C>T p.R876= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs372413216, COSV52430788; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COMT | c.531G>A p.K177= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs772965142, COSV52889397; called by muse, mutect2, varscan2
- CYSLTR2 | c.1002C>T p.F334= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV56166741; called by muse, mutect2, varscan2
- DIO1 | c.627C>T p.Y209= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs750647907, COSV59518744; called by muse, mutect2, varscan2
- EPHB1 | c.534G>A p.Q178= | Silent (SNP) | VAF 64/167 reads (38%) | catalogued as COSV67669188; called by muse, mutect2, varscan2
- F13B | c.835C>T p.L279= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV66373921; called by muse, mutect2
- GCFC2 | c.330G>A p.K110= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs529991040, COSV58082018; called by muse, mutect2, varscan2
- HNRNPA0 | c.264G>T p.S88= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV59246894; called by muse, mutect2, varscan2
- KBTBD2 | c.1687C>T p.L563= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV58364156; called by muse, mutect2, varscan2
- MFAP1 | c.930G>A p.L310= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV51040662; called by muse, mutect2, varscan2
- MUC5AC | c.14370C>G p.L4790= | Silent (SNP) | VAF 76/180 reads (42%) | catalogued as COSV64370595; called by muse, mutect2, varscan2
- MUL1 | c.780G>C p.R260= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV51643091; called by muse, mutect2, varscan2
- PCNX3 | c.5781C>T p.L1927= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100856185; called by muse, mutect2
- POLR1G | c.1278G>A p.K426= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV50004033, COSV50005178; called by muse, mutect2, varscan2
- POU2F3 | c.1098C>G p.L366= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV52793234; called by muse, mutect2, varscan2
- POU3F4 | c.159C>T p.L53= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as rs1377955293, COSV64537841; called by muse, mutect2, varscan2
- SHMT2 | c.795C>T p.P265= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV61075085; called by muse, mutect2, varscan2
- TDRD9 | c.2850C>T p.V950= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV59153885; called by muse, mutect2
- ZNF318 | c.1236C>G p.L412= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1455843087, COSV58936584; called by muse, mutect2, varscan2
- OR5AU1 | c.-69C>G | 5'UTR (SNP) | VAF 26/68 reads (38%) | catalogued as COSV58616077; called by muse, mutect2, varscan2
- UVSSA | c.*9838C>T | 3'UTR (SNP) | VAF 19/54 reads (35%) | catalogued as rs1340857950, COSV61349057; called by muse, mutect2, varscan2
- XIST | n.8217C>T | RNA (SNP) | VAF 15/17 reads (88%) | called by muse, mutect2, varscan2
